Gene-level copy-number profile of tumor specimen HCM-BROD-0048-C71-01A from HCMI case HCM-BROD-0048-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen HCM-BROD-0048-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14130afd-b315-480c-a3d0-4c8eebe73de6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0048-C71-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/02906012-12e8-4294-97d8-f6a3188fa885

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 8,470; copy number 2: 46,628; copy number 3: 734; copy number 4: 2,924; copy number 5: 12; copy number 7: 2; copy number 9: 1; copy number 62: 16; copy number 63: 14; copy number 66: 44.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,239,130–9,240,722, 1 gene (within-gene range 0–1): USP17L16P.
- chr9:20,331,446–20,332,277, 1 gene: AL512635.1.
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:23,500,691–24,592,104, 10 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1.
- chr9:25,676,389–25,678,440, 1 gene: TUSC1.
- chr9:26,066,675–26,118,408, 1 gene: AL353753.1.
- chr9:66,721,158–66,745,929, 3 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr10:104,641,290–105,265,242, 2 genes: SORCS3, SORCS3-AS1.
- chr10:123,323,422–123,323,586, 1 gene: AL160290.2.
- chr10:123,425,713–123,427,640, 1 gene (within-gene range 0–1): AL160290.1.
- chr10:131,092,391–131,311,721, 2 genes: TCERG1L, TCERG1L-AS1.
- chr10:133,070,929–133,241,928, 6 genes: ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX.
- chr11:2,159,779–2,161,221, 1 gene (within-gene range 0–1): INS.
- chr13:22,099,163–22,113,338, 2 genes (within-gene range 0–1): NME1P1, MTND3P1.
- chr13:26,905,362–26,905,861, 1 gene: FGFR1OP2P1.
- chr13:36,674,020–36,697,839, 1 gene: SERTM1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,795,623–205,134,950, 44 genes, copy number 66: ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2.
- chr7:54,752,250–55,862,755, 30 genes, copy number 62–63: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:77,537,295–77,957,503, 6 genes, copy number 5–7: PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA.
- chr7:105,110,704–105,399,308, 7 genes, copy number 5 (within-gene range 4–7): SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P.
- chr7:121,842,368–121,845,131, 1 gene, copy number 5: PNPT1P2.
- chr9:67,512,034–67,515,393, 1 gene, copy number 9: BX664730.1.

Autosomal genes at a single copy (total copy number 1): 5,614. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
